Somatic mutation profile of tumor specimen MMRF_2781_1_BM_CD138pos (aliquot MMRF_2781_1_BM_CD138pos_T1_KHS5U_L15728) from MMRF case MMRF_2781, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.8 years (24,042 days).
Specimen MMRF_2781_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 584a71cb-67ec-484b-a97f-8ae3a66806f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2781_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2781_1_PB_WBC_C3_KHS5U_L15772; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f20915de-6956-45a0-9a29-840cf6051258

The open-access MAF lists 22 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 9, Missense Mutation 6, Intron 2, Splice Site 1, Silent 1, 3'Flank 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A3 | c.3955+1G>A p.X1319_splice | Splice Site (SNP) | VAF 6/96 reads (6%) | catalogued as CS1511099; called by muse, mutect2
- COPA | c.1328A>G p.E443G | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV54106562; called by muse, mutect2
- OR8A1 | c.248T>C p.V83A | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as COSV52508289; called by muse, mutect2
- PSKH2 | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV99405067; called by muse, mutect2, varscan2
- VTN | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782268632, COSV56873113; called by muse, mutect2, varscan2
- CEBPB | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 41/169 reads (24%) | called by muse, mutect2, varscan2
- GLI2 | c.3965A>T p.Q1322L (on ENST00000361492 / NM_001374353.1; = p.Q1339L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- HPF1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- DGKB | c.1143G>A p.L381= | Silent (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
- BHLHE22 | c.*835G>A | 3'UTR (SNP) | VAF 11/70 reads (16%) | catalogued as rs1283846315, COSV100417995; called by muse, mutect2, varscan2
- CDC42SE2 | c.*18-252T>C | Intron (SNP) | VAF 9/16 reads (56%) | catalogued as rs1052052609; called by muse, mutect2, varscan2
- COX15 | c.*1840C>T | 3'UTR (SNP) | VAF 18/120 reads (15%) | called by muse, mutect2, varscan2
- DNAJC25 | c.*553G>T | 3'UTR (SNP) | VAF 6/119 reads (5%) | called by muse, mutect2
- FANCE | c.*590C>G | 3'UTR (SNP) | VAF 34/101 reads (34%) | called by muse, mutect2, varscan2
- IGHJ6 | chr14:105863433 G>C | 5'Flank (SNP) | VAF 10/19 reads (53%) | catalogued as rs1000737670; called by muse, varscan2
- MOB3B | c.*2845C>T | 3'UTR (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- PARM1 | c.*3582C>T | 3'UTR (SNP) | VAF 8/64 reads (13%) | catalogued as rs1246246384; called by muse, mutect2
- PARP8 | c.*3198G>C | 3'UTR (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
- RASSF3 | chr12:64696110 C>A | 3'Flank (SNP) | VAF 4/10 reads (40%) | catalogued as rs111421391; called by muse, varscan2
- SLC12A1 | c.724+1137G>A | Intron (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- SORL1 | c.*570del | 3'UTR (DEL) | VAF 23/71 reads (32%) | called by mutect2, varscan2
- ZNF354C | c.*1600del | 3'UTR (DEL) | VAF 5/18 reads (28%) | called by mutect2, varscan2
